CCDI case PBBYUK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da73544f-bb92-4838-a8d0-4d06c53c7134

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.3 years (477 days).

Biospecimens (3 samples)
- Sample 0DKZ8H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKZ8J: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKZ8N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
